Gene-level copy-number profile of tumor specimen ALCH-ABN4-TTP1-A from ALCHEMIST case ALCH-ABN4, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.1 years (24,884 days).
Specimen ALCH-ABN4-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3fc1136d-7fea-4cb9-99cf-f0f527b7dfe3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ABN4-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/be98f3e7-e13b-448d-81c4-8c639872de4e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 614; copy number 1: 13,164; copy number 2: 43,914; copy number 3: 896; copy number 4: 181; copy number 5: 89; copy number 6: 23; copy number 8: 1; copy number 11: 11; copy number 14: 5; copy number 19: 11.

Homozygous deletions (total copy number 0; autosomes only): 90 genes in 31 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:3,712,200–3,747,373, 3 genes (within-gene range 0–2): TP73-AS2, TP73-AS1, AL136528.1.
- chr3:50,116,022–50,189,075, 3 genes (within-gene range 0–2): SEMA3F-AS1, SEMA3F, AC104450.1.
- chr3:75,384,059–75,395,536, 3 genes: AC139453.2, LSP1P2, AC139453.1.
- chr3:75,435,232–75,580,199, 5 genes (within-gene range 0–1): LINC02018, ENPP7P2, SNRPCP10, AC133041.1, RPS3AP15.
- chr3:126,973,065–127,037,392, 2 genes: AC011199.1, PLXNA1.
- chr7:2,631,986–2,664,802, 1 gene: TTYH3.
- chr7:73,593,194–73,624,543, 2 genes: MLXIPL, AC005089.1.
- chr8:30,729,131–30,767,006, 2 genes (within-gene range 0–2): UBXN8, HIKESHIP3.
- chr9:130,444,961–130,501,274, 1 gene: ASS1.
- chr10:86,935,540–86,969,481, 3 genes (within-gene range 0–1): MMRN2, AC025268.1, SNCG.
- chr11:69,103,493–69,109,094, 1 gene: AP003071.1.
- chr11:73,376,399–73,397,474, 2 genes (within-gene range 0–2): RELT, AP000763.4.
- chr14:99,481,169–99,604,207, 4 genes (within-gene range 0–1): CCNK, CCDC85C, AL110504.1, Y_RNA.
- chr14:103,519,667–103,522,833, 1 gene: CKB.
- chr15:21,293,653–21,295,201, 1 gene: AC068446.1.
- chr15:25,169,337–25,170,804, 2 genes (within-gene range 0–2): DMAC1P1, SNORD115-1.
- chr15:25,194,921–25,220,578, 14 genes (within-gene range 0–2): SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27.
- chr15:41,825,099–41,848,155, 4 genes (within-gene range 0–2): AC020659.2, JMJD7, JMJD7-PLA2G4B, PLA2G4B.
- chr15:41,851,913–41,852,029, 1 gene (within-gene range 0–2): RNA5SP393.
- chr15:73,319,859–73,368,958, 2 genes: HCN4, AC068397.2.
- chr15:99,395,179–99,435,160, 4 genes: LINC02244, AC015660.2, AC015660.3, AC015660.1.
- chr16:58,665,109–58,684,770, 1 gene: SLC38A7.
- chr17:3,510,502–3,636,249, 5 genes (within-gene range 0–1): TRPV3, TRPV1, AC027796.5, AC027796.3, AC027796.1.
- chr17:7,389,727–7,404,097, 3 genes (within-gene range 0–1): PLSCR3, TMEM256-PLSCR3, TMEM256.
- chr17:18,968,789–19,004,764, 2 genes (within-gene range 0–1): FAM83G, AC090286.4.
- chr17:39,728,496–39,747,291, 2 genes (within-gene range 0–2): MIEN1, GRB7.
- chr19:6,379,572–6,412,404, 5 genes: GTF2F1, AC011491.2, MIR6885, MIR6790, AC011491.1.
- chr20:41,359,962–41,366,818, 1 gene (within-gene range 0–2): EMILIN3.
- chr21:43,446,601–43,453,902, 1 gene: LINC00319.
- chr22:24,594,811–24,653,356, 6 genes (within-gene range 0–1): GGT1, AP000356.1, BCRP3, AP000356.4, AP000356.3, AP000356.2.
- chr22:29,705,256–29,731,833, 3 genes (within-gene range 0–1): AC004882.1, AC004882.2, CABP7.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 138 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:51,471,717–55,255,635, 37 genes, copy number 6–19: AC005999.2, ROBO2P1, AC005999.1, RN7SL292P, AC079763.1, AC006320.1, SGO1P2, AC074397.1, POM121L12, HAUS6P1, RNF138P2, RNU1-14P, RN7SKP218, AC009468.2, AC009468.1, LINC01446, RNU2-29P, RAC1P9, AC074348.1, HAUS6P3, LINC02854, AC092848.2, AC092848.1, LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1.
- chr7:56,577,848–56,603,553, 3 genes, copy number 5: AC092447.6, AC092447.1, AC092447.9.
- chr12:31,382,226–31,591,136, 1 gene, copy number 5 (within-gene range 2–5): DENND5B.
- chr12:31,443,792–34,162,238, 65 genes, copy number 5–6 (broad region; genes not listed).
- chr15:21,405,401–21,981,245, 30 genes, copy number 5: POTEB3, MIR3118-3, U6, NF1P9, MIR5701-2, AC183088.4, AC183088.2, AC183088.1, LINC02203, AC183088.3, AC135068.6, AC135068.2, AC135068.12, AC135068.11, AC135068.1, AC135068.4, AC135068.5, AC135068.8, AC135068.7, AC135068.9, AC135068.10, AC135068.3, AC134981.1, MIR3118-4, POTEB, RNU6-631P, ZNF519P3, NF1P2, MIR5701-3, OR11J6P.
- chr21:43,461,960–43,479,534, 2 genes, copy number 6–8: LINC00313, AP001048.1.

Autosomal genes at a single copy (total copy number 1): 10,862. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
